Somatic mutation profile of tumor specimen TARGET-10-PARGBT-09A (aliquot TARGET-10-PARGBT-09A-01D) from TARGET case TARGET-10-PARGBT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.5 years (3,851 days).
Specimen TARGET-10-PARGBT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38eb1f17-8752-498c-88b1-11eec2d61fda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGBT-10A (Blood Derived Normal), aliquot TARGET-10-PARGBT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5677c47-9c32-4303-9b8d-1a17c2c36d6d

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 4, 3'UTR 3, Silent 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4987G>A p.G1663S | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs1346404008, COSV53774710; called by muse, mutect2, varscan2
- CSMD3 | c.2530C>T p.R844W (on ENST00000297405 / NM_001363185.1; = p.R740W on NM_052900.3) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777713609, COSV52105465; called by muse, mutect2, varscan2
- KCNC1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV99789096; called by muse, mutect2
- MUC22 | c.5293G>A p.G1765R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.12); catalogued as rs892626371; called by muse, mutect2, varscan2
- SLC8A2 | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757657881, COSV52639817; called by muse, mutect2, varscan2
- TCEAL3 | c.569del p.G190Afs*19 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as COSV54581534; called by mutect2, pindel, varscan2
- BTRC | c.890A>G p.H297R (on ENST00000370187 / NM_033637.4; = p.H261R on NM_003939.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.078); called by muse, mutect2
- CLEC12B | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF3H | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- KIAA1109 | c.12031G>A p.D4011N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- LEF1 | c.408_409insGCGGCCCCAG p.R137Afs*8 | Frame Shift Ins (INS) | VAF 9/20 reads (45%) | called by mutect2, pindel, varscan2
- SEPTIN9 | c.1298T>C p.L433P (on ENST00000427177 / NM_001113491.2; = p.L415P on NM_006640.4) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TFRC | c.1406del p.G469Dfs*8 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by mutect2, pindel*, varscan2
- TRPM3 | c.2131C>T p.L711F (on ENST00000357533 / NM_001366142.2; = p.L554F on NM_020952.6) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZCCHC8 | c.1376_1377insGGA p.S459delinsRD | In Frame Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- CDK15 | c.117G>A p.A39= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs569785795; called by muse, varscan2
- MYBL1 | c.300A>G p.E100= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- AC112695.1 | n.303T>C | RNA (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- CXCR1 | c.*43A>G | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- MRPL43 | c.465+55T>C | Intron (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- NYNRIN | c.*870G>A | 3'UTR (SNP) | VAF 16/32 reads (50%) | catalogued as rs781505944; called by muse, mutect2, varscan2
- OTUB1 | c.*150G>A | 3'UTR (SNP) | VAF 13/24 reads (54%) | catalogued as rs1338699569; called by muse, mutect2, varscan2
- RBFOX1 | c.318+314G>A | Intron (SNP) | VAF 20/42 reads (48%) | catalogued as rs1190942585; called by muse, mutect2
- SPATA31C1 | n.523-38A>T | Intron (SNP) | VAF 28/128 reads (22%) | called by muse, varscan2
- TBX6 | c.840-28_840-27insGGTATCCTC | Intron (INS) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
